TARGET case TARGET-15-SJMPAL040028 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bdd81a45-511a-414b-9beb-aa53be092593

Demographics
Sex at birth: female; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 17.2 years (6,265 days); Year of diagnosis: 2007; Days to last follow up: 3,182 days (8.7 years).

Follow-up (1 entry)
- Days to follow up: 3,182 days (8.7 years); First event: Relapse; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 43.2 ×10³/µL.

Biospecimens (6 samples)
- Samples TARGET-15-SJMPAL040028-04A, TARGET-15-SJMPAL040028-04A.1, TARGET-15-SJMPAL040028-04A.2, TARGET-15-SJMPAL040028-04A.3, TARGET-15-SJMPAL040028-04B (5 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL040028-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 3182
- Protocol: Singapore
- WBC at Diagnosis: 43.2
- Initial Therapy: hybrid
- Karyotype: 46,XX,t(2;14)(p?11.2;q11.2)[13]/46,XX[7] Disruption of MLL gene
- WHO ALAL Classification: B/M
- WHO RL1: B/M
